Somatic mutation profile of tumor specimen TCGA-2G-AAGY-01A (aliquot TCGA-2G-AAGY-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAGY, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Teratoma, benign; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 28.3 years (10,338 days).
Specimen TCGA-2G-AAGY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae624a7e-aa67-43a2-b17a-c1fe8bb4a8f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGY-10A (Blood Derived Normal), aliquot TCGA-2G-AAGY-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61788a5d-456c-452d-b8a5-9f72fd86cba0

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AVPR1B | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV65638595; called by muse, mutect2, varscan2
- TOR1AIP2 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs770205390, COSV100857461; called by muse, mutect2, varscan2
- ADCK2 | c.422_433dup p.S141_T144dup | In Frame Ins (INS) | VAF 12/86 reads (14%) | called by mutect2, varscan2
- MAT2A | c.497A>G p.E166G | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- PIGR | c.548T>G p.V183G | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SEC16A | c.1328C>A p.T443K | Missense Mutation (SNP) | VAF 69/118 reads (58%) | SIFT tolerated (0.62); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- SELP | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GAREM2 | c.1443C>T p.C481= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- HNRNPA1 | c.954C>T p.Y318= (on ENST00000340913 / NM_031157.4; = p.Y266= on NM_002136.4) | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs753050231; called by muse, mutect2, varscan2
- HYDIN | c.10431G>C p.V3477= | Silent (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- NTN1 | c.1411+292C>T | Intron (SNP) | VAF 49/202 reads (24%) | called by muse, mutect2, varscan2
